Gene-level copy-number profile of specimen HCM-BROD-0926-C16-85N from HCMI case HCM-BROD-0926-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 30.9 years (11,285 days).
Specimen HCM-BROD-0926-C16-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c508a4f8-affa-4453-b413-b7ead0e4a774.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0926-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b3dee7c8-3bbd-4d22-9d85-9cc25a6fcff5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 78; copy number 2: 21,716; copy number 3: 22,225; copy number 4: 11,584; copy number 5: 2,514; copy number 6: 214; copy number 7: 11; copy number 29: 18; copy number 40: 4; copy number 53: 1; copy number 55: 24; copy number 76: 4; copy number 88: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 63 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,212,421–26,833,194, 52 genes, copy number 29–88: MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2.
- chr17:17,591,428–17,770,821, 6 genes, copy number 7 (within-gene range 6–7): AC020558.1, AC020558.5, SMCR2, AC020558.3, AC020558.4, RAI1-AS1.
- chr17:18,476,737–18,551,705, 5 genes, copy number 7 (within-gene range 5–7): LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Autosomal genes at a single copy (total copy number 1): 78. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
